Somatic mutation profile of tumor specimen TCGA-BG-A0M7-01A (aliquot TCGA-BG-A0M7-01A-11W-A062-09) from TCGA case TCGA-BG-A0M7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G2; Age at diagnosis: 60.5 years (22,096 days).
Specimen TCGA-BG-A0M7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a9398b5-a361-4df8-8fab-7b50e91f3673.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M7-10A (Blood Derived Normal), aliquot TCGA-BG-A0M7-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/706bc4cd-e423-49c8-a2b1-9178736b2a79

The open-access MAF lists 69 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.337_339del p.L113del | In Frame Del (DEL) | VAF 42/141 reads (30%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 236/310 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARR3 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV52104363; called by muse, mutect2, varscan2
- ATXN2 | c.2189C>T p.T730M (on ENST00000550104; = p.T570M on NM_002973.4) | Missense Mutation (SNP) | VAF 51/338 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.664); catalogued as rs372595198; called by muse, mutect2, varscan2
- BMP3 | c.1161G>C p.W387C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51087217, COSV51094819; called by muse, mutect2
- C3AR1 | c.1399del p.H467Tfs*28 | Frame Shift Del (DEL) | VAF 68/326 reads (21%) | catalogued as COSV50817892; called by mutect2, pindel, varscan2
- CNTNAP5 | c.3502G>A p.V1168I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375640846, CM1010519; called by muse, mutect2, varscan2
- COL22A1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777346782, COSV57323338; called by muse, mutect2, varscan2
- COL4A2 | c.4712C>G p.A1571G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV64629675; called by muse, mutect2, varscan2
- CPT1A | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs142473901; called by muse, mutect2, varscan2
- CSMD2 | c.6916G>A p.V2306I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs143826784; called by muse, mutect2, varscan2
- DHRS7 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53666388; called by muse, mutect2, varscan2
- DYNC2H1 | c.3630G>T p.W1210C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750054685, COSV62097111; called by muse, mutect2, varscan2
- FGFR2 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 133/197 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60638873; called by muse, mutect2, varscan2
- FSIP2 | c.20519T>C p.F6840S | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58089589; called by muse, mutect2, varscan2
- HSPA4 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1461396494, COSV59182711; called by muse, mutect2, varscan2
- INPP5J | c.1633G>A p.V545M (on ENST00000331075 / NM_001284285.2; = p.V177M on NM_001002837.2) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs371488095; called by muse, mutect2, varscan2
- KALRN | c.5790G>A p.R1930= (on ENST00000360013 / NM_001024660.4; = p.R233= on NM_007064.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 14/108 reads (13%) | catalogued as COSV52258702; called by muse, mutect2
- KCNMA1 | c.3295C>T p.R1099C (on ENST00000286628 / NM_001161352.2; = p.R1041C on NM_002247.4) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54257454; called by muse, mutect2
- KLK5 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568810143, COSV60450631; called by muse, mutect2, varscan2
- KMO | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63809040; called by muse, mutect2
- MTPN | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.934); catalogued as rs1423921992, COSV101262927, COSV67599324; called by muse, mutect2, varscan2
- MYO15A | c.5692C>T p.R1898* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs201163103; called by muse, mutect2, varscan2
- NHS | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66271555; called by muse, mutect2, varscan2
- NKTR | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51772825; called by muse, mutect2, varscan2
- OR51T1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 180/420 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs781697460, COSV59025275; called by muse, mutect2, varscan2
- OR5D18 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV61737593; called by muse, mutect2
- PIGG | c.2237G>A p.R746Q (on ENST00000453061 / NM_001127178.3; = p.R738Q on NM_017733.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs962499498, COSV56318929, COSV56320311; called by muse, mutect2, varscan2
- PLEKHA3 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 75/322 reads (23%) | catalogued as rs767588949, COSV52294989; called by muse, mutect2, varscan2
- POGZ | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 121/571 reads (21%) | catalogued as COSV55037286; called by muse, mutect2, varscan2
- PTPRF | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63443741, COSV63444400; called by muse, mutect2, varscan2
- RBM22 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV52272122; called by muse, mutect2
- RELN | c.3450G>T p.E1150D | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.952); catalogued as COSV58990420, COSV59010528; called by muse, mutect2, varscan2
- SAPCD2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs749355882, COSV68836375; called by muse, mutect2, varscan2
- SCYL3 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs758190718, COSV53676551; called by muse, mutect2
- SGCG | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405454039, COSV54558398; called by muse, mutect2, varscan2
- SGK1 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV52811104; called by muse, mutect2, varscan2
- SIPA1L1 | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62171044; called by muse, mutect2, varscan2
- SPOP | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 192/256 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV61654385; called by muse, mutect2, varscan2
- SYNE2 | c.15324G>A p.M5108I | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV59955109, COSV59956326; called by muse, mutect2
- TANC2 | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs748373533, COSV101267250, COSV67336270; called by muse, mutect2, varscan2
- TRPC7 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752775491, COSV61452329, COSV61459414; called by muse, mutect2, varscan2
- UBR2 | c.4112G>A p.R1371K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.562); catalogued as COSV65750616; called by muse, mutect2, varscan2
- UBR3 | c.3625A>G p.M1209V | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV55851947; called by muse, mutect2, varscan2
- ZC3H12B | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100161479, COSV59049256; called by muse, mutect2, varscan2
- ZMYND8 | c.194C>T p.P65L (on ENST00000311275 / NM_001363741.2; = p.P85L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53685474; called by muse, mutect2
- ZNF106 | c.5053C>T p.R1685C | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55516115; called by muse, mutect2
- ZNF445 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV68539027; called by muse, mutect2, varscan2
- ZNF773 | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.825); catalogued as COSV56589057, COSV56589294; called by muse, mutect2
- KIAA1109 | c.7460_7461del p.T2487Sfs*21 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | called by pindel, varscan2
- ATP8A2 | c.2499C>T p.H833= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs751085900, COSV54948912, COSV54972551; called by muse, mutect2, varscan2
- B3GALT4 | c.522G>A p.T174= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs113873727, COSV65851737; called by muse, mutect2, varscan2
- B4GALT2 | c.1098G>A p.P366= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs747653687, COSV58844335; called by muse, mutect2, varscan2
- CCDC136 | c.3378C>A p.P1126= | Silent (SNP) | VAF 114/805 reads (14%) | catalogued as COSV52800870; called by mutect2, varscan2
- CSMD2 | c.10344C>T p.H3448= | Silent (SNP) | VAF 54/152 reads (36%) | catalogued as rs768925616, COSV53923692; called by muse, mutect2, varscan2
- DPH1 | c.1215C>G p.P405= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV53985158; called by muse, mutect2, varscan2
- HASPIN | c.1638C>T p.S546= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs146710070; called by muse, mutect2, varscan2
- IGHV2-5 | c.21G>A p.T7= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs376683788; called by muse, mutect2, varscan2
- KIF20A | c.1554A>G p.P518= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as COSV67510050; called by muse, mutect2
- NLGN4X | c.1284C>T p.A428= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs201588956, COSV52023293; ClinVar: likely benign; called by muse, mutect2
- NSD2 | c.2271C>T p.F757= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV56388915; called by muse, mutect2, varscan2
- PRUNE2 | c.8697C>T p.I2899= | Silent (SNP) | VAF 51/153 reads (33%) | catalogued as rs1406814394, COSV56317277; called by muse, mutect2, varscan2
- RALGAPA2 | c.5610C>T p.S1870= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs372557790; called by muse, mutect2
- SEMA4D | c.1902G>A p.T634= | Silent (SNP) | VAF 81/210 reads (39%) | catalogued as rs748015780, COSV59395850; called by muse, mutect2, varscan2
- SIM1 | c.1320G>A p.S440= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs1164025324, COSV53490653, COSV99492722; called by muse, mutect2, varscan2
- SLC25A34 | c.507C>T p.G169= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs571515007, COSV53817421; called by muse, mutect2, varscan2
- USP6 | c.3846C>T p.G1282= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1319295998, COSV51485408; called by muse, mutect2, varscan2
- ZNF462 | c.3690G>A p.T1230= | Silent (SNP) | VAF 169/467 reads (36%) | catalogued as rs1366611653, COSV52933951; called by muse, mutect2
